Gene-level copy-number profile of tumor specimen TCGA-77-8153-01A from TCGA case TCGA-77-8153, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 77.4 years (28,253 days).
Specimen TCGA-77-8153-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.7f9d700b-5bcf-4f99-8f44-6a175598076d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-77-8153-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a84cd7c7-a89f-478a-a698-8527b6600c68

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 27,139; copy number 2: 29,175; copy number 3: 1,950; copy number 4: 801; copy number 5: 316; copy number 6: 430.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-77-8153-01A-11D-2391-01): tumor purity 0.76, ploidy 1.77, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:190,992,639–190,993,567, 1 gene: RAB1AP1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 746 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–45,895,970, 710 genes, copy number 5–6 (within-gene range 0–6) (broad region; genes not listed).
- chr20:35,115,364–35,769,867, 36 genes, copy number 5: EDEM2, AL135844.1, PROCR, AL356652.1, RNA5SP483, MMP24OS, MT1P3, MMP24, AL121753.2, AL121753.1, EIF6, FAM83C-AS1, FAM83C, UQCC1, GDF5-AS1, GDF5, MIR1289-1, CEP250, CEP250-AS1, FO393401.1, C20orf173, ERGIC3, RPL36P4, FER1L4, RPL37P1, SPAG4, CPNE1, AL109827.1, RN7SKP271, RNU6-759P, RBM12, NFS1, ROMO1, RBM39, RPF2P1, U6.

Autosomal genes at a single copy (total copy number 1): 25,944. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
